TCGA case TCGA-ZM-AA0N — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis; Tissue source site: University of Ulm. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d6c4198b-6c69-40e5-a8eb-b2de3ac0b2b7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Croatia; Age at index: 44 years; Year of birth: 1969; Vital status: Alive.

Diagnoses (2)
1. Seminoma, NOS (the primary disease): ICD-O-3 morphology code: 9061/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 44.1 years (16,094 days); Year of diagnosis: 2013; Method of diagnosis: Orchiectomy; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IB; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 634 days (1.7 years); Ajcc serum tumor markers: S0; Sites of involvement: Tunica Albuginea.
   Pathology details: Intratubular germ cell neoplasia present: Yes; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: No; Timepoint category: Postoperative.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Seminoma, NOS), site: Intra-abdominal lymph nodes. Age at diagnosis: 45.4 years (16,584 days); Days to diagnosis: 490 days (1.3 years); Prior treatment: Yes.

Follow-up (4 entries)
- Days to follow up: 330 days; Disease response: Tumor Free.
- Day 490 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Intra-abdominal lymph nodes; Days to progression: 490 days (1.3 years).
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Follow-up.
- Follow-up contact recording only the day: day 634.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0: Lactate Dehydrogenase 461; Alpha Fetoprotein 1.63; Human Chorionic Gonadotropin 0.
- Day 323: Lactate Dehydrogenase 221; Alpha Fetoprotein 1.13; Testosterone 14.7.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Fertility history: Did not achieve pregnancy following 12 or more months of unprotected intercourse; Undescended testis history: No.

Family history
- Relative with cancer history: no.
- Relative with cancer history: yes; Relationship type: Natural Mother; Relationship primary diagnosis: Breast Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-ZM-AA0N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 290 mg.
  Slide TCGA-ZM-AA0N-01A-02-TS2: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-ZM-AA0N-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-ZM-AA0N-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; History hypospadias: No; History fertility: Did not achieve pregnancy following > or = 12 months of unprotected intercourse; Tumor status: Tumor free.
- Primary pathology: Submitted tumor site: Testes; Testis tumor macroextent: Involves extratesticular structures: Tunica albuginea; Intratubular germ cell neoplasm: Present; Lymphovascular invasion: Yes; Post orchi lymph node dissection: No; First treatment success: No Measureable Tumor or Tumor Markers.
- Primary pathology, Histology list, Histology: Histologic diagnosis: Seminoma, NOS.
- Primary pathology, Pre orchi serum marker info: Pre orchi LDH: 461; Pre orchi hcg: 0; Pre orchi afp: 1.63.
- Primary pathology, Post orchi serum marker info: Post orchi LDH: 221; Post orchi afp: 1.13; Post orchi testosterone: 14.66.
- Primary pathology, Molecular test result list: Molecular test result: Lactate Dehydrogenase (LDH) - Normal; Molecular test result: Human Chorionic Gonadotropin (HCG) - Normal; Molecular test result: Alpha Fetaprotein (AFP) - Normal.
- Follow-up form: Lost to follow-up: No; Post orchi lymph node dissection: No; Treatment outcome first course: No Measureable Tumor or Tumor Markers.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 634 days; disease-specific survival: no event (censored), 634 days; disease-free interval: event (new tumor event after initially disease-free), 490 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 490 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-ZM-AA0N-01A-21D-A434-01): tumor purity 0.33, ploidy 3.51, whole-genome doublings 1.
